Somatic mutation profile of tumor specimen TCGA-HT-A614-01A (aliquot TCGA-HT-A614-01A-11D-A29Q-08) from TCGA case TCGA-HT-A614, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.6 years (17,392 days).
Specimen TCGA-HT-A614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b627aaeb-139e-4cc5-a595-ee67ce0f479e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A614-10A (Blood Derived Normal), aliquot TCGA-HT-A614-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3be399-b1bf-464c-8bad-85d17a3e8249

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 5, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 18/25 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH7 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52920975; called by muse, mutect2
- AKAP13 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63457868; called by muse, mutect2, varscan2
- AQP10 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs761850160, COSV61475084; called by muse, mutect2, varscan2
- ARNTL2 | c.1158A>T p.Q386H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53825916; called by muse, mutect2, varscan2
- ATRX | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 111/152 reads (73%) | catalogued as COSV64876933; called by muse, mutect2, varscan2
- DAP | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1226243473, COSV50143757; called by muse, mutect2, varscan2
- FAAH2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 46/59 reads (78%) | catalogued as rs746695435, COSV66507789; called by muse, mutect2, varscan2
- FNBP4 | c.1821G>A p.R607= | Splice Region (SNP) | VAF 25/57 reads (44%) | catalogued as COSV55446258; called by muse, mutect2, varscan2
- HK1 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53858558; called by muse, mutect2, varscan2
- KLK15 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140896741; called by muse, mutect2, varscan2
- MYH4 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as rs373223401; called by muse, mutect2, varscan2
- PIGS | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV52024568; called by muse, mutect2, varscan2
- PPP6C | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV65207975; called by muse, mutect2, varscan2
- RAVER2 | c.1176G>T p.L392F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV53807522, COSV53811492; called by muse, mutect2, varscan2
- RNF145 | c.677T>G p.V226G (on ENST00000424310 / NM_001199383.2; = p.V254G on NM_144726.2) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV50865405, COSV50866638; called by muse, mutect2, varscan2
- SLC35D1 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV52431413; called by muse, mutect2, varscan2
- SMARCA4 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV60795083; called by muse, mutect2, varscan2
- SPRED3 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100634217; called by muse, varscan2
- TRGC2 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs368796657; called by muse, mutect2, varscan2
- UBE2G2 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.742); catalogued as rs782079899, COSV58368401; called by muse, mutect2, varscan2
- USP10 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV54749050; called by muse, mutect2
- YTHDC1 | c.1432C>T p.Q478* (on ENST00000344157 / NM_001031732.4; = p.Q460* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60010548; called by muse, mutect2, varscan2
- ZNF385D | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55756659; called by muse, mutect2
- THOC3 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APOB | c.9321C>T p.N3107= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs72653101, COSV51936637; called by muse, mutect2, varscan2
- AQP12A | c.393G>T p.L131= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1461767758, COSV100538809; called by muse, mutect2, varscan2
- CCDC149 | c.255A>G p.K85= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1343838667, COSV60879100, COSV60882489; called by muse, mutect2, varscan2
- CSF3 | c.279C>T p.P93= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56640887; called by muse, mutect2
- NUP188 | c.5055G>A p.Q1685= | Silent (SNP) | VAF 28/299 reads (9%) | catalogued as COSV65330948; called by muse, mutect2
- OR52N4 | c.684C>A p.V228= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- WDR54 | c.774G>A p.L258= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV51963391; called by muse, mutect2, varscan2
- DCHS2 | n.3631C>T | RNA (SNP) | VAF 22/73 reads (30%) | catalogued as rs1163928835, COSV59727109; called by muse, mutect2
